Somatic mutation profile of tumor specimen C3N-00194-02 (aliquot CPT0014160006) from CPTAC case C3N-00194, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 51.7 years (18,885 days).
Specimen C3N-00194-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bacb02b-3e15-4294-b7cb-1fe6c1325a44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00194-31 (Blood Derived Normal), aliquot CPT0015040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1175b12c-d9a9-49e7-b407-65d357fa8895

The open-access MAF lists 60 somatic variants for this specimen: 46 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Frame Shift Del 7, Nonsense Mutation 4, Splice Site 3, Intron 2, 3'UTR 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.269A>T p.N90I | Missense Mutation (SNP) | VAF 133/407 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143985153, CM004284, COSV56546846, COSV56547129; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD30BL | c.764C>A p.T255K | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.196); catalogued as rs1248387408; called by muse, mutect2, varscan2
- CFAP52 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as rs775639416, COSV100234649; called by muse, mutect2, varscan2
- DTWD1 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1349922146, COSV52071861, COSV52072012; called by muse, mutect2, varscan2
- DYSF | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 137/506 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs139258703, CM055157; called by muse, mutect2, varscan2
- ERBB2 | c.2827C>A p.Q943K | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54073307; called by muse, mutect2, varscan2
- KIAA0319L | c.392T>A p.L131* | Nonsense Mutation (SNP) | VAF 43/224 reads (19%) | catalogued as rs766020293; called by muse, mutect2, varscan2
- NSD1 | c.6703C>T p.H2235Y | Missense Mutation (SNP) | VAF 275/675 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.099); catalogued as rs1289043115; called by muse, mutect2, varscan2
- PDE1C | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.262); catalogued as rs762050534, COSV58520743; called by muse, mutect2, varscan2
- PFKL | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV57394605; called by muse, mutect2, varscan2
- PRX | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 119/474 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99398219; called by muse, mutect2, varscan2
- SI | c.4062+1G>T p.X1354_splice | Splice Site (SNP) | VAF 25/94 reads (27%) | catalogued as COSV100017400; called by muse, mutect2, varscan2
- SLC17A9 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs374675240; called by muse, mutect2, varscan2
- AC068580.4 | c.286T>A p.F96I | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AMDHD2 | c.195del p.G66Dfs*62 | Frame Shift Del (DEL) | VAF 10/93 reads (11%) | called by mutect2, pindel, varscan2
- ATP6V1B2 | c.1279G>C p.A427P | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ATP9A | c.874A>C p.K292Q | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C17orf100 | c.327del p.A110Pfs*56 | Frame Shift Del (DEL) | VAF 59/244 reads (24%) | called by mutect2, pindel, varscan2
- CCT6B | c.1340T>G p.I447S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, varscan2
- CDH23 | c.4400T>A p.F1467Y | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DEFB134 | c.59-9_59-1del p.X20_splice | Splice Site (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- DNMT3L | c.649C>A p.Q217K | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMILIN1 | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- ERLEC1 | c.526-3_526delinsTTTT p.X176_splice | Splice Site (ONP) | VAF 8/71 reads (11%) | called by mutect2*, pindel
- FCHO1 | c.1445A>C p.H482P | Missense Mutation (SNP) | VAF 13/311 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2
- FSCN1 | c.1216G>C p.A406P | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- GLIS3 | c.71G>A p.S24N | Missense Mutation (SNP) | VAF 54/482 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- GLYATL3 | c.638G>A p.C213Y | Missense Mutation (SNP) | VAF 112/456 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- HS3ST4 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 38/179 reads (21%) | called by muse, mutect2, varscan2
- MED30 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIDEAS | c.856del p.Q286Rfs*32 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- NINL | c.2200del p.R734Gfs*8 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel
- NKPD1 | c.1024del p.L342Wfs*64 | Frame Shift Del (DEL) | VAF 34/105 reads (32%) | called by mutect2, pindel, varscan2
- OR4C16 | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- PCDH15 | c.5574del p.K1859Sfs*4 | Frame Shift Del (DEL) | VAF 109/467 reads (23%) | called by mutect2, pindel, varscan2
- PNPLA1 | c.658T>C p.F220L (on ENST00000394571 / NM_001374623.1; = p.F125L on NM_173676.2) | Missense Mutation (SNP) | VAF 79/301 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PROM1 | c.655T>C p.Y219H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RANBP10 | c.1100G>T p.S367I | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2
- SGPP1 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- SLC5A3 | c.778C>G p.P260A | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPC24 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.75); called by muse, mutect2
- SPHK2 | c.348C>G p.C116W | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- SUPV3L1 | c.2177C>G p.P726R | Missense Mutation (SNP) | VAF 82/291 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SWSAP1 | c.493del p.Q165Sfs*33 (on ENST00000312423; = p.Q186Sfs*33 on NM_175871.4) | Frame Shift Del (DEL) | VAF 90/434 reads (21%) | called by mutect2, pindel*, varscan2
- TSC22D1 | c.3074A>C p.N1025T (on ENST00000458659 / NM_183422.4; = p.N96T on NM_006022.4) | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- YLPM1 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | called by muse, mutect2, varscan2
- GANAB | c.1326C>T p.D442= | Silent (SNP) | VAF 35/120 reads (29%) | called by muse, mutect2, varscan2
- HS3ST4 | c.198G>A p.Q66= | Silent (SNP) | VAF 38/180 reads (21%) | called by muse, mutect2, varscan2
- LONRF3 | c.1677C>T p.F559= (on ENST00000371628 / NM_001031855.3; = p.F518= on NM_024778.5) | Silent (SNP) | VAF 24/135 reads (18%) | catalogued as rs761393744, COSV59152302; called by muse, varscan2
- LRRC49 | c.1458A>G p.A486= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as rs956094812; called by muse, mutect2, varscan2
- NR2F1 | c.759C>T p.R253= | Silent (SNP) | VAF 16/382 reads (4%) | catalogued as COSV59070007; called by muse, mutect2
- PCDHGA5 | c.1905A>G p.R635= | Silent (SNP) | VAF 21/590 reads (4%) | called by muse, mutect2
- RUNDC1 | c.36G>A p.T12= | Silent (SNP) | VAF 85/358 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.10581T>A p.I3527= (on ENST00000591111; = p.I3481= on NM_003319.4) | Silent (SNP) | VAF 53/257 reads (21%) | called by muse, mutect2, varscan2
- VPS39 | c.2124T>A p.I708= (on ENST00000348544 / NM_001301138.2; = p.I697= on NM_015289.5) | Silent (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- AP4B1 | c.*16del | 3'UTR (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- CABP7 | c.-50_-49del | 5'UTR (DEL) | VAF 26/120 reads (22%) | called by mutect2, pindel
- LINC01948 | n.390G>A | RNA (SNP) | VAF 32/185 reads (17%) | called by muse, mutect2, varscan2
- PRSS27 | c.237-41C>T | Intron (SNP) | VAF 20/182 reads (11%) | catalogued as rs200616593; called by muse, mutect2, varscan2
- VPS13A | c.100+27C>T | Intron (SNP) | VAF 22/177 reads (12%) | called by muse, mutect2, varscan2
